Somatic mutation profile of tumor specimen TCGA-IR-A3L7-01A (aliquot TCGA-IR-A3L7-01A-21D-A20U-09) from TCGA case TCGA-IR-A3L7, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 37.1 years (13,559 days).
Specimen TCGA-IR-A3L7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2ee7d5d-7954-4c06-a888-793f190033bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IR-A3L7-10A (Blood Derived Normal), aliquot TCGA-IR-A3L7-10A-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f38d56b-a9ca-4b79-9b41-15a37999bb56

The open-access MAF lists 31 somatic variants for this specimen: 19 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 9, Splice Site 1, Nonsense Mutation 1, Intron 1, Frame Shift Del 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATXN1 | c.1528A>G p.T510A | Missense Mutation (SNP) | VAF 55/65 reads (85%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as COSV55219986; called by muse, mutect2, varscan2
- BIRC2 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57162121; called by muse, mutect2, varscan2
- BRIX1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as rs374761203; called by muse, mutect2, varscan2
- ERICH6 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV55801349; called by muse, mutect2, varscan2
- FCGBP | c.6536T>C p.V2179A | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as COSV55441659; called by muse, mutect2, varscan2
- KRTAP5-9 | c.263G>T p.C88F | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as COSV73200211; called by muse, mutect2, varscan2
- MYH4 | c.2888T>C p.L963P | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs751620819, COSV55120316; called by muse, mutect2, varscan2
- NME6 | c.197G>A p.R66H (on ENST00000415053; = p.R74H on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs144390600; called by muse, mutect2, varscan2
- PGAP6 | c.2073G>T p.W691C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51740355; called by muse, mutect2, varscan2
- SLAMF8 | c.789G>C p.K263N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99222814; called by mutect2, varscan2
- SLC5A11 | c.1777G>A p.V593I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs572775623, COSV61740330; called by muse, mutect2, varscan2
- STAT5B | c.1713G>T p.W571C | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53183693; called by muse, mutect2, varscan2
- SV2C | c.914-2A>G p.X305_splice | Splice Site (SNP) | VAF 54/149 reads (36%) | catalogued as COSV59222373; called by muse, mutect2, varscan2
- SYNDIG1L | c.200G>A p.W67* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as rs776876170, COSV59047764; called by muse, mutect2, varscan2
- TSC22D3 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59777681; called by muse, mutect2, varscan2
- TTLL6 | c.1757A>T p.K586I (on ENST00000393382 / NM_001130918.3; = p.K279I on NM_173623.3) | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV64977708; called by muse, mutect2, varscan2
- UBAP2L | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55175323; called by muse, mutect2, varscan2
- VLDLR | c.505A>G p.R169G | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.102); catalogued as rs777739092, COSV66074083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCOR1 | c.3698_3705del p.R1233Kfs*5 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- ANO2 | c.2583G>A p.Q861= (on ENST00000356134 / NM_001278597.3; = p.Q865= on NM_001278596.3) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV59028789; called by muse, mutect2, varscan2
- CARS1 | c.1665G>A p.L555= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV53453607; called by muse, varscan2
- CMBL | c.369C>T p.A123= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV56983913; called by muse, mutect2, varscan2
- CNTN2 | c.1344C>G p.A448= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs778178054, COSV59350793, COSV59350837, COSV59352319; called by muse, mutect2
- MYH9 | c.4482G>A p.E1494= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV53388145; called by muse, mutect2, varscan2
- PPP1R1C | c.219G>C p.V73= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV54716958; called by muse, mutect2, varscan2
- RIPK1 | c.180C>T p.L60= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV52530061; called by muse, mutect2, varscan2
- STARD6 | c.504G>A p.V168= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV57142666; called by muse, mutect2, varscan2
- TLR9 | c.1884C>T p.S628= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as rs200907891, COSV100645595; called by muse, mutect2, varscan2
- EME2 | c.569+42G>A | Intron (SNP) | VAF 5/33 reads (15%) | catalogued as rs143812454; called by mutect2, varscan2
- LAGE3 | c.*2C>G | 3'UTR (SNP) | VAF 25/88 reads (28%) | catalogued as COSV100635697; called by muse, mutect2, varscan2
- MIR514A1 | n.85G>A | RNA (SNP) | VAF 16/71 reads (23%) | catalogued as rs192021879; called by muse, mutect2, varscan2
